TCGA case TCGA-VS-A9UC — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cca23650-1b06-4977-91e8-f35e73e70c48

Demographics
Sex at birth: female; Country of residence at enrollment: Brazil; Age at index: 32 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 32.3 years (11,790 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC pathologic T: T2b; AJCC pathologic N: NX; AJCC pathologic M: MX; FIGO stage: Stage IIB; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 146 days; Days to treatment end: 203 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 146 days; Days to treatment end: 173 days; Treatment dose: 3,240 cGy; Treatment outcome: Stable Disease; Number of fractions: 18; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 5; Treatment outcome: Stable Disease; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment frequency: Once Weekly.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Treatment dose: 3,240 cGy; Treatment outcome: Stable Disease; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.

Follow-up (4 entries)
- Day -2 (prior to adjuvant therapy): ECOG performance status: 1.
- Days to follow up: 511 days (1.4 years); Disease response: With Tumor.
- Days to follow up: 691 days (1.9 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 825.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Perimenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used.
- Timepoint category: Initial Diagnosis; Weight: 76 kg; Height: 153 cm; BMI: 32.5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VS-A9UC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 80 mg.
  Slide TCGA-VS-A9UC-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VS-A9UC-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VS-A9UC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Peri (6-12 months since last menstrual period); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 4; Total pregnancy count: 4; Tobacco smoking history indicator: 1; Performance status timing: Pre-Adjuvant Therapy; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); New tumor event diagnosis indicator: No.
- Treatment, Radiation therapy info: Radiation therapy xrt type: 3D conformal.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent fractions total: 5.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 825 days; disease-specific survival: no event (censored), 825 days; progression-free interval: no event (censored), 825 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VS-A9UC-01A-11D-A42N-01): tumor purity 0.72, ploidy 2.2, whole-genome doublings 0.
